Somatic mutation profile of tumor specimen C3L-05891-54 (aliquot CPT0344460002) from CPTAC case C3L-05891, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 69.7 years (25,450 days).
Specimen C3L-05891-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea9b2e37-a413-48b0-ae2e-c439fe223faf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05891-50 (Buccal Cell Normal), aliquot CPT0344430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e202d4cc-c566-4063-a2ac-0e706f91547f

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRB3 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 20/691 reads (3%) | catalogued as rs1555368345, COSV54655786; ClinVar: uncertain significance; called by muse, mutect2
- ITGBL1 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 24/402 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs755517767; called by muse, mutect2
- PLPP7 | c.155C>G p.A52G | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV64835834; called by muse, mutect2, varscan2
- MYBL2 | c.1506-1G>A p.X502_splice | Splice Site (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- PCGF1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.143); called by muse, mutect2
